Gene-level copy-number profile of tumor specimen TCGA-CU-A0YR-01A from TCGA case TCGA-CU-A0YR, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 84.0 years (30,674 days).
Specimen TCGA-CU-A0YR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.321f7819-40df-4d1a-a2dd-739bedaf21e0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CU-A0YR-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 822 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2 (sample pair TCGA-CU-A0YR-01A|TCGA-CU-A0YR-10A); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0d90e0cd-ce23-4734-88bc-85ba39b4c204

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,218; copy number 2: 14,607; copy number 3: 22,759; copy number 4: 16,405; copy number 5: 3,059; copy number 6: 660; copy number 7: 277; copy number 8: 111; copy number 10: 166; copy number 11: 76; copy number 12: 34; copy number 14: 131; copy number 17: 173; copy number 18: 111; copy number 36: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CU-A0YR-01A-12D-A10T-01): tumor purity 0.47, ploidy 3.3, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,093 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:158,578,919–168,314,426, 288 genes, copy number 7–10 (broad region; genes not listed).
- chr3:10,759,350–14,574,792, 75 genes, copy number 8–17 (broad region; genes not listed).
- chr6:129,831,244–137,045,180, 143 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr8:76,406,654–76,524,356, 1 gene, copy number 7 (within-gene range 3–7): LINC01111.
- chr8:97,241,742–113,493,281, 252 genes, copy number 10–17 (broad region; genes not listed).
- chr8:117,794,490–129,683,770, 171 genes, copy number 12–18 (within-gene range 3–18) (broad region; genes not listed).
- chr11:105,974,826–107,586,903, 21 genes, copy number 7: RNU6-277P, AP000813.1, MSANTD4, KBTBD3, AASDHPPT, AP001001.1, AP001001.2, LINC02719, AP002001.3, AP002001.1, AP002001.2, AP003173.1, GUCY1A2, AP001282.2, AP001282.1, ASS1P13, AP000766.1, CWF19L2, SMARCE1P1, ALKBH8, AP001823.1.
- chr11:107,600,379–107,600,868, 1 gene, copy number 7: AP000889.2.
- chr17:36,861,674–39,747,291, 109 genes, copy number 8–36 (broad region; genes not listed).
- chr20:11,536,406–13,996,443, 29 genes, copy number 7: AL109837.2, AL109837.3, AL109837.1, PGAM3P, AL161938.1, LINC00687, RN7SKP111, AL080274.1, BTBD3, AL035448.1, AL109838.1, AL136460.1, PA2G4P2, LINC01722, AL078623.1, AL133331.1, LINC01723, SPTLC3, AL109983.1, ISM1, ISM1-AS1, AL050320.1, AL121782.1, TASP1, GAPDHP2, ESF1, NDUFAF5, SEL1L2, RNU6-278P.
- chr20:14,003,508–14,223,325, 3 genes, copy number 7: RPS3P1, AIMP1P1, RN7SL864P.

Autosomal genes at a single copy (total copy number 1): 1,218. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
